Somatic mutation profile of tumor specimen TCGA-55-8299-01A (aliquot TCGA-55-8299-01A-11D-2284-08) from TCGA case TCGA-55-8299, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.9 years (22,626 days).
Specimen TCGA-55-8299-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9591b9ec-827d-4cba-8bca-fb464015977e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8299-10B (Blood Derived Normal), aliquot TCGA-55-8299-10B-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fc27300-1278-4615-9e67-c569939f294e

The open-access MAF lists 190 somatic variants for this specimen: 148 protein-altering or splice-affecting, 39 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 132, Silent 39, Nonsense Mutation 10, Splice Site 5, 3'Flank 1, Splice Region 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | hotspot (GDC flag); catalogued as COSV58820842, COSV58825712; called by muse, mutect2, varscan2
- ABCG8 | c.743C>A p.A248D | Missense Mutation (SNP) | VAF 17/261 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as rs533359544, COSV55395817; called by muse, mutect2
- ACSL6 | c.1478A>G p.D493G (on ENST00000379240; = p.D518G on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99732729; called by muse, mutect2
- ADAM12 | c.559A>T p.N187Y | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV100900054; called by muse, mutect2
- ALOX15B | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV101205569; called by muse, mutect2
- ALPP | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101235088; called by muse, mutect2
- AMER1 | c.1810T>A p.Y604N | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100365361; called by muse, mutect2
- AMER1 | c.1256C>A p.P419H | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV100365363; called by muse, mutect2
- ANK2 | c.1570G>T p.D524Y | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99999897; called by muse, mutect2
- ANKRD11 | c.7651C>A p.P2551T | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99968355; called by muse, mutect2
- ANO4 | c.863A>G p.N288S (on ENST00000392977 / NM_001286615.2; = p.N253S on NM_178826.4) | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.996); catalogued as rs148799316; called by muse, mutect2
- ARHGEF15 | c.1517T>C p.V506A | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV100729981; called by muse, mutect2
- ASB15 | c.414C>A p.N138K | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV99306224; called by muse, mutect2
- ASMT | c.640G>A p.V214M (on ENST00000381229; = p.V242M on NM_004043.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/460 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs369639982; called by muse, mutect2
- ATOH7 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV101028469, COSV65447716; called by muse, mutect2
- BBS10 | c.327G>T p.M109I | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99674540; called by muse, mutect2
- BCL6B | c.523C>G p.R175G | Missense Mutation (SNP) | VAF 38/480 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.104); catalogued as COSV99546442, COSV99546768; called by muse, mutect2
- BOD1L1 | c.5605G>T p.D1869Y | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV99238442; called by muse, mutect2
- CACNA1D | c.767-1G>T p.X256_splice | Splice Site (SNP) | VAF 12/219 reads (5%) | catalogued as rs1198815045, COSV99856674; called by muse, mutect2
- CARD6 | c.392C>T p.T131I | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV99620230; called by muse, mutect2
- CCDC197 | c.13G>A p.D5N | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100113590, COSV100113597; called by muse, mutect2
- CCNA1 | c.1045C>T p.L349F | Missense Mutation (SNP) | VAF 10/292 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); catalogued as COSV55223457; called by muse, mutect2
- CNRIP1 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.149); catalogued as rs1207243722; called by muse, mutect2
- COL6A3 | c.5901G>T p.E1967D | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.34); catalogued as COSV55083879, COSV55093933; called by muse, mutect2
- CPA5 | c.694A>G p.I232V | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.117); catalogued as COSV100812239; called by muse, mutect2, varscan2
- CPAMD8 | c.2656A>G p.M886V (on ENST00000651564; = p.M839V on NM_015692.5) | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs553931663, COSV101488416; called by muse, mutect2
- CUBN | c.8756-1G>A p.X2919_splice | Splice Site (SNP) | VAF 22/248 reads (9%) | catalogued as COSV100912081; called by muse, mutect2
- DGKI | c.2427G>A p.Q809= | Splice Region (SNP) | VAF 6/56 reads (11%) | catalogued as COSV55935838, COSV99932574; called by muse, mutect2
- DPF3 | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV100818423; called by muse, mutect2, varscan2
- DSCAM | c.2369T>C p.I790T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV101259184; called by muse, mutect2
- DSG1 | c.1486C>G p.P496A | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99935601; called by muse, mutect2
- EFNA3 | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100860793; called by muse, mutect2
- F8 | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 14/421 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100811254, COSV64273047; called by muse, mutect2
- FAM71B | c.1524G>T p.E508D | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV100261822; called by muse, mutect2
- FAN1 | c.1733A>T p.N578I | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as COSV100755837; called by muse, mutect2
- FAT3 | c.5758T>A p.Y1920N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99962267; called by muse, mutect2
- FLG2 | c.7103G>A p.R2368K | Missense Mutation (SNP) | VAF 22/275 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.444); catalogued as COSV101165606; called by muse, mutect2
- FLNA | c.625C>A p.L209M | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100774295; called by muse, mutect2
- GALNT14 | c.250A>C p.S84R | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV100204098; called by muse, mutect2
- GBA3 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.351); catalogued as COSV101545472; called by muse, mutect2
- GLI3 | c.2222T>A p.L741H | Missense Mutation (SNP) | VAF 14/247 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101229738; called by muse, mutect2
- GLRA4 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 36/668 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV101009563; called by muse, mutect2
- GOLGA2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 34/492 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs1204251912, COSV68597023; called by muse, mutect2
- GP6 | c.724+1G>T p.X242_splice | Splice Site (SNP) | VAF 14/190 reads (7%) | catalogued as COSV100117403; called by muse, mutect2
- GPR137B | c.1072C>A p.P358T | Missense Mutation (SNP) | VAF 29/634 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.271); catalogued as rs997089893; called by muse, mutect2
- HNRNPU | c.1988G>T p.G663V (on ENST00000283179; = p.G725V on NM_004501.3) | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV99309920; called by muse, mutect2
- HRNR | c.760T>C p.S254P | Missense Mutation (SNP) | VAF 46/928 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as rs1037787067, COSV100913004; called by muse, mutect2
- IGSF10 | c.3851C>T p.P1284L | Missense Mutation (SNP) | VAF 11/243 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99176696; called by muse, mutect2
- IRF8 | c.1172T>A p.M391K | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV99236093; called by muse, mutect2
- KCNB2 | c.1108G>T p.A370S | Missense Mutation (SNP) | VAF 11/298 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.925); catalogued as rs1459304544, COSV101578670; called by muse, mutect2
- KRTAP10-6 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 35/516 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.354); catalogued as COSV100551706; called by muse, mutect2
- L1CAM | c.3234G>T p.W1078C | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as COSV100648873, COSV62829305; called by muse, mutect2
- L1CAM | c.3233G>T p.W1078L | Missense Mutation (SNP) | VAF 21/442 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100648876; called by muse, mutect2
- LGI2 | c.716A>G p.K239R | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.4); PolyPhen benign (0.395); catalogued as COSV66122777; called by muse, mutect2
- MAGEC1 | c.1633C>G p.P545A | Missense Mutation (SNP) | VAF 47/950 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as COSV53571668; called by muse, mutect2
- MED12 | c.2456G>T p.R819L | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.168); catalogued as rs1192740859, COSV100376252; called by muse, mutect2
- METTL2B | c.625G>T p.V209F | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99299666; called by muse, mutect2
- MINDY4 | c.698C>T p.S233L | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV99518219; called by muse, mutect2
- MORF4L2 | c.600C>G p.Y200* | Nonsense Mutation (SNP) | VAF 15/183 reads (8%) | catalogued as COSV64611593; called by muse, mutect2
- MYO3A | c.278G>C p.G93A | Missense Mutation (SNP) | VAF 18/332 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV99778473; called by muse, mutect2
- NAV1 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs986162199; called by muse, mutect2
- NFATC1 | c.2495G>C p.S832T (on ENST00000427363 / NM_001278669.2; = p.S819T on NM_172387.3) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as COSV99500665; called by muse, mutect2
- OPN4 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV54114807, COSV99618043; called by muse, mutect2
- OPRPN | c.326T>C p.L109P | Missense Mutation (SNP) | VAF 12/452 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1269554933, COSV101271075; called by muse, mutect2
- OR13C4 | c.710C>A p.A237E | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99470029; called by muse, mutect2
- OR2T11 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58186920; called by muse, mutect2, varscan2
- OR4C13 | c.174C>G p.Y58* | Nonsense Mutation (SNP) | VAF 20/509 reads (4%) | catalogued as COSV101634140, COSV73648626; called by muse, mutect2
- OR4F6 | c.295G>T p.V99F | Missense Mutation (SNP) | VAF 13/434 reads (3%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.125); catalogued as rs868302386; called by muse, mutect2
- OR4K14 | c.826T>C p.Y276H | Missense Mutation (SNP) | VAF 7/115 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100520341; called by muse, mutect2
- OR6T1 | c.607T>C p.S203P | Missense Mutation (SNP) | VAF 6/161 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100189761; called by muse, mutect2
- PCDH17 | c.2945T>C p.V982A | Missense Mutation (SNP) | VAF 5/131 reads (4%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV100931442; called by muse, mutect2
- PDE6C | c.1582C>G p.L528V | Missense Mutation (SNP) | VAF 13/249 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV101008569; called by muse, mutect2
- PELI1 | c.259G>T p.V87L | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100735069; called by muse, mutect2
- PIRT | c.346A>G p.K116E | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.319); catalogued as COSV101652662; called by muse, mutect2
- PJVK | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100359434, COSV57868685; called by muse, mutect2
- PLOD1 | c.1480A>G p.M494V | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as rs144007935; called by muse, mutect2, varscan2
- PMFBP1 | c.2719G>C p.E907Q (on ENST00000537465; = p.E902Q on NM_031293.3) | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV52825461; called by muse, mutect2, varscan2
- POLA1 | c.4191C>A p.Y1397* | Nonsense Mutation (SNP) | VAF 8/130 reads (6%) | catalogued as COSV100985037; called by muse, mutect2
- PPL | c.2854C>T p.Q952* | Nonsense Mutation (SNP) | VAF 12/347 reads (3%) | catalogued as COSV99277479; called by muse, mutect2
- PSMD3 | c.878-1G>A p.X293_splice | Splice Site (SNP) | VAF 14/166 reads (8%) | catalogued as COSV99227571; called by muse, mutect2
- RAP2C | c.182C>G p.T61S | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100747276; called by muse, mutect2
- RHAG | c.968G>T p.R323M | Missense Mutation (SNP) | VAF 12/207 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.188); catalogued as COSV100006348; called by muse, mutect2
- S1PR1 | c.1053C>A p.S351R | Missense Mutation (SNP) | VAF 25/305 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.558); catalogued as COSV100541481, COSV59514643; called by muse, mutect2
- SAGE1 | c.1820A>T p.N607I | Missense Mutation (SNP) | VAF 11/321 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148235147, COSV100186692; called by muse, mutect2
- SETD7 | c.530A>G p.E177G | Missense Mutation (SNP) | VAF 17/227 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99918354; called by muse, mutect2
- SLC17A6 | c.208C>A p.R70S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); catalogued as COSV54134325, COSV99580811; called by muse, mutect2
- SLC19A2 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 19/286 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.284); catalogued as COSV99356807; called by muse, mutect2
- SMOC1 | c.754G>T p.A252S | Missense Mutation (SNP) | VAF 14/264 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV100734334; called by muse, mutect2
- SNW1 | c.1334A>G p.Q445R | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV99473087; called by muse, mutect2
- STAM | c.1210G>T p.V404L | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.115); catalogued as rs782273741; called by muse, mutect2
- TBC1D21 | c.605G>T p.G202V | Missense Mutation (SNP) | VAF 14/175 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100311194; called by muse, mutect2
- TENM1 | c.37C>A p.P13T | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.024); catalogued as COSV100949127; called by muse, mutect2
- TOP3A | c.1654G>T p.G552C | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100328928; called by muse, mutect2
- TPK1 | c.402G>T p.Q134H | Missense Mutation (SNP) | VAF 8/211 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0.344); catalogued as COSV100765340; called by muse, mutect2
- TRPC7 | c.35G>A p.R12H | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs758800404, COSV61464424; called by muse, mutect2
- TSHZ3 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 7/112 reads (6%) | catalogued as COSV53683113; called by muse, mutect2
- VIPR2 | c.838C>A p.P280T | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.993); catalogued as COSV100056603; called by muse, mutect2
- Z84488.1 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT tolerated, low confidence (0.84); catalogued as COSV100889428, COSV100889482; called by muse, mutect2
- ZFP91 | c.493A>T p.T165S | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV60160634; called by muse, mutect2
- ZFX | c.2308C>G p.H770D | Missense Mutation (SNP) | VAF 19/343 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100457321; called by muse, mutect2
- ZGRF1 | c.1540A>G p.N514D | Missense Mutation (SNP) | VAF 9/149 reads (6%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV100005348; called by muse, mutect2
- ZIC3 | c.1061-1G>A p.X354_splice | Splice Site (SNP) | VAF 35/778 reads (4%) | catalogued as COSV99798357; called by muse, mutect2
- ZNF160 | c.2048G>T p.G683V | Missense Mutation (SNP) | VAF 15/306 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61999042; called by muse, mutect2
- ZNF248 | c.16G>T p.E6* | Nonsense Mutation (SNP) | VAF 10/224 reads (4%) | catalogued as COSV100627469; called by muse, mutect2
- ZNF831 | c.34C>A p.P12T | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV64043927; called by muse, mutect2
- ZP4 | c.349C>G p.H117D | Missense Mutation (SNP) | VAF 42/708 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV100850579, COSV63912987; called by muse, mutect2
- AC244197.3 | c.424G>A p.V142I | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.05); called by muse, mutect2
- ADAMTS16 | c.210C>A p.H70Q | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.025); called by muse, mutect2
- AMHR2 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.026); called by muse, mutect2
- ARHGEF6 | c.617C>G p.T206R | Missense Mutation (SNP) | VAF 25/346 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- BCHE | c.716C>A p.P239H | Missense Mutation (SNP) | VAF 15/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2
- CBFA2T3 | c.653C>A p.S218Y | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.855); called by muse, mutect2
- CFAP45 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 10/302 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- COL23A1 | c.1031C>A p.P344H | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- CPNE8 | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 13/204 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.103); called by muse, mutect2
- CRYBG1 | c.4676G>T p.G1559V | Missense Mutation (SNP) | VAF 21/272 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); called by muse, mutect2
- DLX5 | c.284A>G p.Y95C | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2
- EIF3E | c.1171G>T p.V391L | Missense Mutation (SNP) | VAF 14/209 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.14); called by muse, mutect2
- GAB3 | c.1122G>T p.L374F | Missense Mutation (SNP) | VAF 9/262 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- IGHV3-23 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 42/1203 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.35); called by muse, mutect2
- IGKV1-5 | c.78G>T p.M26I | Missense Mutation (SNP) | VAF 23/344 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.176); called by muse, mutect2
- IGKV1-5 | c.77T>A p.M26K | Missense Mutation (SNP) | VAF 23/343 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- IGKV1D-17 | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 33/556 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ITGA7 | c.1232G>A p.G411E (on ENST00000555728; = p.G367E on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- ITGA8 | c.698T>A p.V233D | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.194); called by muse, mutect2
- LGR6 | c.911T>A p.L304Q (on ENST00000367278 / NM_001017403.1; = p.L252Q on NM_021636.3) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MAGEL2 | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.011); called by muse, mutect2
- MAP1B | c.4588T>A p.S1530T | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- MME | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- MYH13 | c.1669C>A p.Q557K | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.044); called by muse, mutect2
- NAT8 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- NXF3 | c.1104C>A p.Y368* | Nonsense Mutation (SNP) | VAF 17/338 reads (5%) | called by muse, mutect2
- OR1L8 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- OR2A2 | c.551T>A p.L184H | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR4C12 | c.69A>T p.K23N | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.027); called by muse, mutect2
- OR4L1 | c.475C>A p.Q159K | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- OR51G2 | c.112T>A p.F38I | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.02); called by muse, mutect2
- OR5A2 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OVOL1 | c.148T>A p.S50T | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2
- PANK1 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 13/439 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- PAPPA2 | c.1561G>T p.G521* | Nonsense Mutation (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- PCDH19 | c.1097A>T p.Y366F | Missense Mutation (SNP) | VAF 9/204 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PCDHB8 | c.878T>C p.F293S | Missense Mutation (SNP) | VAF 11/403 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PKNOX2 | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 18/254 reads (7%) | SIFT tolerated (0.44); PolyPhen benign (0.154); called by muse, mutect2
- SCN11A | c.2125G>C p.V709L | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- TCEAL6 | c.400C>A p.L134M | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- UTRN | c.3283G>T p.V1095L | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- ZNF438 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 10/298 reads (3%) | called by muse, mutect2
- ACTA1 | c.126C>T p.H42= | Silent (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- AOC2 | c.1693C>T p.L565= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as COSV99519952; called by muse, mutect2
- ASXL2 | c.3867C>T p.F1289= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV99710254; called by muse, mutect2, varscan2
- CACNA1B | c.4263G>A p.E1421= | Silent (SNP) | VAF 26/358 reads (7%) | catalogued as COSV53152320; called by muse, mutect2
- CD300C | c.9C>T p.A3= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100423184; called by muse, mutect2
- CFAP45 | c.262C>A p.R88= | Silent (SNP) | VAF 19/267 reads (7%) | catalogued as COSV100928463, COSV63649790; called by muse, mutect2
- CYP26A1 | c.678C>A p.I226= | Silent (SNP) | VAF 32/260 reads (12%) | catalogued as COSV99814583; called by muse, mutect2, varscan2
- DHX38 | c.1065G>T p.L355= | Silent (SNP) | VAF 5/60 reads (8%) | catalogued as rs1464522185; called by muse, mutect2
- FBN2 | c.8427C>T p.L2809= | Silent (SNP) | VAF 9/251 reads (4%) | catalogued as COSV99325136; called by muse, mutect2
- FRMPD3 | c.2286G>T p.L762= | Silent (SNP) | VAF 10/156 reads (6%) | called by muse, mutect2
- GPR156 | c.1609C>A p.R537= | Silent (SNP) | VAF 38/584 reads (7%) | catalogued as rs575756351, COSV59943160; called by muse, mutect2
- GTF3C1 | c.1374G>T p.L458= | Silent (SNP) | VAF 6/113 reads (5%) | catalogued as COSV100648991; called by muse, mutect2
- HUWE1 | c.2382G>A p.V794= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV99470734; called by muse, mutect2
- LIN52 | c.312C>T p.L104= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as COSV101624987; called by muse, mutect2
- MBTPS2 | c.912C>T p.P304= | Silent (SNP) | VAF 13/251 reads (5%) | catalogued as COSV100810678; called by muse, mutect2
- MMS22L | c.2493G>A p.G831= | Silent (SNP) | VAF 8/170 reads (5%) | catalogued as COSV99246145; called by muse, mutect2
- MOB3B | c.90G>T p.L30= | Silent (SNP) | VAF 24/328 reads (7%) | catalogued as COSV99218192; called by muse, mutect2
- MUC17 | c.1437C>T p.S479= | Silent (SNP) | VAF 60/936 reads (6%) | called by muse, mutect2
- NEB | c.11277C>T p.D3759= | Silent (SNP) | VAF 14/234 reads (6%) | called by muse, mutect2
- OR10S1 | c.771C>A p.A257= | Silent (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- OR7C1 | c.189C>A p.L63= | Silent (SNP) | VAF 22/221 reads (10%) | catalogued as COSV99934791; called by muse, mutect2
- PAPPA | c.1071G>A p.V357= | Silent (SNP) | VAF 5/90 reads (6%) | called by muse, mutect2
- PDZRN4 | c.2334C>T p.A778= (on ENST00000402685 / NM_001164595.2; = p.A520= on NM_013377.4) | Silent (SNP) | VAF 15/340 reads (4%) | catalogued as COSV100113682; called by muse, mutect2
- PLCB2 | c.1056C>T p.G352= | Silent (SNP) | VAF 8/195 reads (4%) | catalogued as rs1291991563; called by muse, mutect2
- PMPCB | c.135A>C p.T45= | Silent (SNP) | VAF 20/396 reads (5%) | catalogued as COSV99971110; called by muse, mutect2
- PRAMEF12 | c.1299G>T p.G433= | Silent (SNP) | VAF 18/284 reads (6%) | catalogued as rs1202998819, COSV100743470; called by muse, mutect2
- PSME4 | c.2295G>T p.L765= | Silent (SNP) | VAF 9/292 reads (3%) | called by muse, mutect2
- PXDN | c.3592C>A p.R1198= | Silent (SNP) | VAF 24/442 reads (5%) | catalogued as COSV53237614, COSV99412394; called by muse, mutect2
- PXDNL | c.1839C>A p.S613= | Silent (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- RSBN1 | c.153G>T p.A51= | Silent (SNP) | VAF 30/368 reads (8%) | catalogued as COSV99792857; called by muse, mutect2
- S1PR2 | c.978G>T p.L326= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- SHANK1 | c.339T>C p.D113= | Silent (SNP) | VAF 8/136 reads (6%) | catalogued as COSV99520272; called by muse, mutect2
- SIRT1 | c.645G>A p.L215= | Silent (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- TCN1 | c.459C>A p.A153= | Silent (SNP) | VAF 26/279 reads (9%) | called by muse, mutect2
- TRIM69 | c.384A>G p.P128= | Silent (SNP) | VAF 9/171 reads (5%) | catalogued as rs762294525, COSV100274405; called by muse, mutect2
- TRPM1 | c.2787G>A p.V929= | Silent (SNP) | VAF 10/182 reads (5%) | catalogued as COSV56634565, COSV99855396; called by muse, mutect2
- TRPM8 | c.3027C>G p.L1009= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV100223640; called by muse, mutect2
- VILL | c.1578G>T p.V526= | Silent (SNP) | VAF 11/207 reads (5%) | catalogued as COSV99378462; called by muse, mutect2
- WWC2 | c.2976G>T p.P992= | Silent (SNP) | VAF 13/184 reads (7%) | catalogued as COSV67860824; called by muse, mutect2
- COPS9 | chr2:240129925 C>A | 3'Flank (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- KIR3DX1 | n.554G>T | RNA (SNP) | VAF 17/154 reads (11%) | catalogued as rs1298919048; called by muse, mutect2, varscan2
- PDGFD | c.125-36636G>T | Intron (SNP) | VAF 45/452 reads (10%) | called by muse, mutect2, varscan2
